Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A03F, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A03F-01A (Primary Tumor).

ICD-0-3
Adenocarcinoma, Mucinous 8480/3
Site: Cecum C18.0
w 3/28/11

Internal Sample ID

Diagnosis/Diagnoses:

Right hemicolectomy specimen with an ulcerated cecal carcinoma of the histological type of a moderately differentiated, partially mucus-forming colorectal adenocarcinoma measuring 5.5 cm in its largest diameter and subtotally enclosing the cecum. Invasive tumor spread into all intestinal wall layers as far as the mesocolic fatty tissue and subserosa. Colon mucosa otherwise with some tubular adenomas with moderate epithelial dysplasia (synonym: low-grade intra-epithelial neoplasia).

Oral and aboral resection margins and greater omentum tumor-free.

Four of twenty-nine regional lymph nodes with metastases from the colon carcinoma.

Tumor stage therefore: pT3, pN2 (4/29); G2.

Source: NCI Genomic Data Commons file 3ef0c595-a01d-4147-85ba-eb40e0e62a77 (TCGA-AA-A03F.F373544C-93EA-40F2-9C69-1FBCE4EB31E4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).